Somatic mutation profile of tumor specimen TCGA-CF-A3MF-01A (aliquot TCGA-CF-A3MF-01A-12D-A21A-08) from TCGA case TCGA-CF-A3MF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: Low Grade; Age at diagnosis: 34.4 years (12,557 days).
Specimen TCGA-CF-A3MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfd5a8b8-312a-4a4a-9b94-d0ab73e2d0bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A3MF-10A (Blood Derived Normal), aliquot TCGA-CF-A3MF-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36702d8e-4104-4775-b5d7-0a0e905d21bb

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV53967310; called by muse, mutect2, varscan2
- ATG16L2 | c.1047C>A p.S349R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV58360821; called by muse, mutect2, varscan2
- AXIN2 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 5/100 reads (5%) | catalogued as COSV104406432; called by muse, mutect2
- CACNA1A | c.5605G>A p.G1869S | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64188555; called by muse, mutect2, varscan2
- CDKN1A | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 102/118 reads (86%) | catalogued as rs1260849045, COSV55187626, COSV99781593; called by muse, mutect2, varscan2
- DCAF12 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV63511452; called by muse, mutect2, varscan2
- KLHDC4 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767846001, COSV54505730; called by muse, varscan2
- KMT2C | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 32/834 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51274506; called by muse, mutect2
- KRI1 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs147727983; called by muse, mutect2, varscan2
- MDGA1 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs370621790; called by muse, mutect2, varscan2
- OR4C3 | c.179dup p.L61Pfs*8 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | catalogued as rs777276396; called by mutect2, pindel
- RFX4 | c.2122C>T p.R708C (on ENST00000392842 / NM_213594.3; = p.R614C on NM_032491.6) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs563415881, COSV57571564; called by muse, mutect2, varscan2
- SEMA5B | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1447682629, COSV52089348, COSV99532373; called by muse, mutect2, varscan2
- SLC5A1 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1293590621, COSV56682909; called by muse, mutect2
- SMTN | c.2636T>A p.V879E | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV60774750; called by muse, mutect2, varscan2
- XG | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766062680, COSV66985624; called by muse, mutect2, varscan2
- ZFYVE28 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as rs761192658, COSV52106360; called by muse, mutect2, varscan2
- ZMYND8 | c.3133T>C p.Y1045H (on ENST00000311275 / NM_001363741.2; = p.Y1019H on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53682182; called by muse, mutect2, varscan2
- ZNF10 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- CDCA7 | c.93G>A p.S31= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs142079460; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIDO1 | c.2496C>T p.V832= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV56612692; called by muse, mutect2, varscan2
- HSD11B2 | c.1116G>A p.L372= | Silent (SNP) | VAF 56/209 reads (27%) | catalogued as COSV52096528; called by muse, mutect2, varscan2
- OPRL1 | c.1101G>A p.P367= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs138878509; called by muse, mutect2, varscan2
